Surgical pathology report (de-identified scan), TCGA case TCGA-HB-A43Z, project TCGA-SARC (Sarcoma), tissue source site University of North Carolina, specimen TCGA-HB-A43Z-01A (Primary Tumor).

[page 1 of 3]
SURGICAL PATHOLOGY REVISED REPORT

Case Number :

Diagnosis:

A: Uterus, hysterectomy and bilateral salpingo-oophorectomy:

Cervix

- No tumor seen

ICD-O3
Leiomyosarcoma, NOS
8890/3

Endometrium

- Atrophic endometrium

Site: CCRF: uterus, NOS
C55.9

- Endometrial polyp, 2.5 x 2.0 x 0.6 cm

Path:
uterus, myometrium
C54.2

Myometrium

- Leiomyosarcoma, tumor size 10 x 9.5 x 4.5 cm (see comment)

- Tumor necrosis is present

- Tumor infiltrates the myometrium but does not involve the endometrium or serosa

- Lymphovascular space invasion present (e.g. A10)

- Adenomyosis

- Leiomyoma, small, benign

- AJCC pathologic staging: pT1b, pNx, pMx

8/23/12
RD

Ovary, right, oophorectomy

- Atrophic ovary, no tumor seen

Fallopian tube, right, salpingectomy

- No tumor seen

Ovary, left, oophorectomy

- Atrophic ovary, no tumor seen

Fallopian tube, left, salpingectomy

- No tumor seen

lw
8/14/12

Comment:

Sections of the smooth muscle tumor in the myometrium show a proliferation of pleomorphic spindle cells showing marked cellular pleomorphism, significantly increased mitotic activity (>10 mitoses per 10 high power fields counted), and tumor necrosis. In addition, the tumor is frankly infiltrative (e.g. A2) and lymphovascular space invasion is also present (e.g. A10). Immunohistochemical evaluation performed on the previous endometrial biopsy (supports classification as a

[page 2 of 3]
leiomyosarcoma. No carcinoma component is identified to qualify for a carcinosarcoma.

Clinical History:

-year-old female with a pelvic mass.

Gross Description:

Received is one appropriately labeled container, additionally labeled "uterus, cervix, bilateral tubes and ovaries." It holds a 690 gram, 12.3 x 8.3 x 7.2 cm uterus with attached bilateral adnexa. The serosa is dark gray and smooth. The 3.0 x 2.5 cm ectocervix has a 0.6 cm patent os. The 2.7 cm long endocervical canal is tan and trabeculated. Within the endometrial cavity there is a 10.0 x 9.5 x 4.5 cm tan soft, somewhat nodular mass with central yellow soft areas. The mass appears to originate from the myometrium. The uninvolved myometrium is tan, firm and up to 3.5 cm thick. The endometrium is tan-yellow and ranges in thickness from 0.3 to 0.6 cm. There is a 2.5 x 2.0 x 0.6 cm polyp attached to the anterior endometrium. On section, the polyp appears to be contained to the endometrial surface.

The right ovary is 3.8 x 1.9 x 1.0 cm. The outer surface is tan and smooth. On section, the cut surface is grossly unremarkable.

The attached fimbriated fallopian tube is 4.0 cm in length x 0.4 cm in diameter. Along the outer surface there are several translucent fluid-filled cysts up to 0.6 cm. The remainder of the outer surface is dark red and smooth. On sectioning, the lumen appears patent.

The left ovary is 2.8 x 1.5 x 1.2 cm. The outer surface is tan and smooth. On section, the cut surface is tan/yellow, firm and unremarkable. The attached fimbriated fallopian tube is roughly 4.1 cm in length x 0.6 cm in diameter. Along the length of the tube there are multiple translucent cloudy fluid-filled cysts up to 0.4 cm. The remainder of the outer surface is dark brown and smooth. On section, the lumen appears patent.

Block summary:

- A1 - anterior cervix and endocervical canal
- A2 - myometrial mass, anterior wall; section taken with serosal surface
- A3,A4 - myometrial mass, anterior wall, bisected section to include serosal surface

[page 3 of 3]
A5,A6 - endometrial polyp, anterior wall, base, bisected section, full thickness
A7,A8 - additional sections of anterior endomyometrium to include myometrial nodule
A9 - anterior cervix and endocervical canal
A10,A11 - myometrial mass, posterior wall, bisected section to include serosal surface
A12,A13 - myometrial mass, posterior wall, bisected section to include serosal surface
A14,A15 - sections of posterior endomyometrium to include myometrial nodule
A16 - right ovary
A17 - right fallopian tube
A18 - left ovary
A19 - right fallopian tube
Tissue remains in formalin.

Tumor is submitted to Tissue Procurement.

Source: NCI Genomic Data Commons file f3d516cf-71c4-4a05-a934-5c6d9417f6bc (TCGA-HB-A43Z.098E7467-ACC6-498A-B064-7AB0DD8C8D59.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).